Surgical pathology report (de-identified scan), TCGA case TCGA-67-3773, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site St Joseph's Medical Center (MD), specimen TCGA-67-3773-01A (Primary Tumor).

[page 1 of 10]
TISSUES:

- A. LYMPH NODE
- B. LYMPH NODE
- C. LYMPH NODE
- D. LYMPH NODE
- E. LYMPH NODE
- F. LUNG-LEFT LOWER LOBE

DES: P88305 - 88305
P88307 - 88307
P88313 - 88313
P88331 - 88331
D50175 - RESECTION
D50177 - REGIONAL LYMPH
88305TC - LEVEL IV - GROS
88307TC - LEVEL V - GROSS
88313TC - SPECIAL STAINS
88331TC - PATHOLOGY CONSU
1 - SURGICAL SPECIM
T28700 - LT LO LOBE LUNG
T08000 - LYMPH NODE

Continued on next page ...

[page 2 of 10]
[REDACTED]

MARKERS: 88305, 88305TC, 88307, 88307TC, 88313, SPECIAL STAINS - GRP II, 88331,
PATH CONSULT FS, RES, RLN, SURGICAL SPECIMEN

[REDACTED]

[REDACTED]

CLINICAL HISTORY

PRE-OPERATIVE DIAGNOSIS: LEFT LOWER LOBE LUNG CA [REDACTED]

[REDACTED]

FINAL DIAGNOSIS

- A. "LEVEL 9L LYMPH NODE": LYMPH NODE NEGATIVE FOR TUMOR.
- B. "LEVEL 6 LYMPH NODES": MULTIPLE LYMPH NODES NEGATIVE FOR TUMOR.
- C. "LEVEL 5 LYMPH NODES": TWO (2) LYMPH NODES NEGATIVE FOR TUMOR.
- D. "POSTERIOR HILAR LYMPH NODE": LYMPH NODE NEGATIVE FOR TUMOR.
- E. "SUPERIOR SEGMENTAL LYMPH NODE": LYMPH NODE NEGATIVE FOR TUMOR.
- F. "SUPERIOR SEGMENT, LEFT LUNG LOWER LOBE" (SEGMENTECTOMY): MODERATELY DIFFERENTIATED ADENOCARCINOMA OF LUNG SPANNING 1.5 CM IN DIMENSION AND FOCALLY PENETRATING THE VISCERAL PLEURA (HIGHLIGHTED ON AN ELASTIC STAIN). THE INKED SURGICAL MARGIN OF RESECTION IS NEGATIVE

Continued on next page ...

[page 3 of 10]
FINAL DIAGNOSIS

(Continued)

FOR TUMOR. PATCHY MILD NON-SPECIFIC CHRONIC INFLAMMATION WITH
SCATTERED EPITHELIOID GRANULOMATA.

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "9L" and consists of a 0.7 cm anthracotic lymph node; bisected and submitted, 2 (1) labeled "FSP" for frozen section.

FROZEN SECTION DIAGNOSIS: Negative for tumor.

B. The specimen is submitted fresh for frozen section as "level 6" and consists of four anthracotic lymph nodes ranging 0.4 cm to 1.4 cm in dimension. The largest nodule is inked blue and bisected. The specimen is submitted in toto, 5 (1) labeled "FSP" for frozen section.

FROZEN SECTION DIAGNOSIS: Multiple lymph nodes negative for tumor.

C. The specimen is submitted fresh for frozen section as "level 5" and consists of two anthracotic lymph nodes measuring 0.5 cm and 1.3 cm in greatest dimension. The smaller lymph node is inked blue. The specimen is bisected and submitted in toto, 4 (1) labeled "FSP" for frozen section.

FROZEN SECTION DIAGNOSIS: Multiple lymph nodes negative for tumor.

D. The specimen is submitted fresh for frozen section as "posterior hilar node" and consists of a 1.2 cm anthracotic lymph node; bisected and submitted, 2 (1) labeled "FSP" for frozen section.

FROZEN SECTION DIAGNOSIS: Negative for tumor.

E. The specimen is submitted fresh for frozen section as "superior segmental node" and consists of a 0.5 cm anthracotic lymph node; bisected and submitted, 2 (1) labeled "FSP" for frozen section.

FROZEN SECTION DIAGNOSIS: Negative for tumor.

F. The specimen is submitted fresh as "left lower lobe superior segmentectomy" and consists of a wedge lung resection measuring 8 x 5 x 1.5 cm and weighing 24 gms with two stapled surgical margins measuring 7 cm and 3 cm in length. The pleural surface is tan purple with diffuse

Continued on next page ...

[page 4 of 10]
GROSS DESCRIPTION

(Continued)

anthracotic pigmentation and a 0.5 cm puckered area. A mass is palpable underlying the puckered pleural surface. Sectioning reveals a 1.5 x 1.3 x 1 cm pale tan firm mass 0.4 cm from the stapled margin and abutting the pleural surface. The pleural surface is inked black and the stapled margin is inked blue. No additional masses or lesions are identified. The lung parenchyma is red purple and spongy. Representative sections are submitted, 6 (5):

Cassettes 1, 2 and 3: Mass
Cassettes 4 and 5: Normal lung

Note: A portion of the tumor is submitted for [REDACTED] studies.

PRIORITY**SYNOPTIC REPORT**

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: WEDGE RESECTION
LATERALITY: LEFT
TUMOR SITE: SUPERIOR SEGMENT OF LOWER LOBE
TUMOR SIZE: 1.5 CM
HISTOLOGIC TYPE: ADENOCARCINOMA
HISTOLOGIC GRADE: I-II
EXTENT OF INVASION: LUNG PARENCHYMA
EXTENSION TO PLEURA/OTHER STRUCTURES (SPECIFY): VISCERAL PLEURA
ADDITIONAL PERTINENT FINDINGS - ATELECTASIS, PNEUMONIA, ETC: (SEE NARRATIVE)

MARGINS:
BRONCHIAL: N/A

Continued on next page ...

[page 5 of 10]
SYNOPTIC REPORT

(Continued)

PARENCHYMAL: NEGATIVE

VASCULAR: N/A

DISTANCE TO PERTINENT MARGIN(S) (AS APPLICABLE): 0.4 CM

VENOUS INVASION: NOT IDENTIFIED

ARTERIAL (LARGE VESSEL) INVASION: NOT IDENTIFIED

LYMPH NODE:

N1 - # INVOLVED/# EXAMINED: 0/2

N2 - # INVOLVED/#EXAMINED: 0/MULTIPLE

N3 - # INVOLVED/# EXAMINED: 0/4

OTHER PERTINENT FINDINGS: (SEE NARRATIVE)

pTNM STAGE: pT2, pN0, MX

*** End of Report ***

[page 6 of 10]
CLINICAL HISTORY

HISTORY: 2 CM SOLITARY NODULE LOCATED IN THE POSTERIOR BASAL REGION.
(+) MEDIASTINAL LYMPH NODES. JUNE 2009 (ACUTE TRACHEAL BRONCHITIS).
X-RAY FINDINGS: 2 CM LEFT LUNG NODULE (+ PET SUV 2.6)

GROSS DESCRIPTION

Tech [REDACTED]

RECEIVED: Slide 90 cc Fluid* X Fresh Fixed Type Fix

* Volume may reflect total of specimen, fixative, and/or collection fluid.

APPEARANCE: X Clear Cloudy Foamy Bloody

Clotted Tissue Color COLORLESS

PREP: 6 Smear(s) Diff Quick(s) Filter(s) 1 Cell Block(s)

Cytospin(s) - 2 Singles(s) Double(s)

H&E Unstained

Comment:

FINAL DIAGNOSIS

LUNG, LEFT POSTERIOR (FINE NEEDLE ASPIRATION BIOPSY): POSITIVE FOR MALIGNANCY. WELL DIFFERENTIATED ADENOCARCINOMA CONSISTENT WITH LUNG PRIMARY. THE DIAGNOSIS IS SUPPORTED BY IMMUNOPHENOTYPE WITH STRONG CK7 AND TTF-1 POSITIVITY, FAINT P53 POSITIVITY AND NEGATIVE MESOTHELIAL MARKERS (CALRETININ, CD15, WT1, CK5/6). CK20 IS NEGATIVE, AND Ki67 PROLIFERATIVE RATE IS MILDLY ELEVATED. TUMOR IS PRESENT IN A BACKGROUND OF INFLAMMATION AND FIBROSIS WITH BENIGN PULMONARY ELEMENTS.

INTRADEPARTMENTAL CONSULTATION: [REDACTED] [REDACTED]

[page 7 of 10]
[REDACTED]

FINAL DIAGNOSIS

(Continued)

REVIEWED BY PATHOLOGIST: [REDACTED]

Unless otherwise specified, the performance characteristics of the immunoperoxidase stains performed here have been confirmed by the [REDACTED] [REDACTED] [REDACTED] approved by the U.S. Food and Drug Administration, although such approval is not necessary.

[REDACTED]

[page 8 of 10]
to surgery

NONCONTRAST CHEST CT

INDICATION: Cough. Abnormal chest x-ray.

TECHNIQUE: Axial imaging with reformatted images on acquisition scanner.

FINDINGS: There is a noncalcified soft tissue mass density in the left lower lobe series 3 image #44 measured at 2.2 x 1.3 cm. This is of concern for neoplasm. There are bilateral apical opacities right greater than left. There is posterolateral pleural based density bilaterally right greater than left. This may be due to scarring. Mass or infiltrate cannot be excluded and follow-up is advised. The lungs appear hyperexpanded with peribronchial thickening and prominence of the interstitial markings. There are other regions in the right upper lobe with interstitial density suggesting scarring. There is a posterior pleural based density as seen on image #25. There may be a nodular density in the right upper lobe on image #30 versus scarring measuring 7 mm. There is a very small nodular density lateral portion right upper lobe on image #33. There is no evidence of pleural fluid. There are degenerative changes in the spine. There is vascular calcification. There are a few nodes in the mediastinum. There is a pretracheal node measuring 1.8 x 0.8 cm. There are a few smaller nodes at the AP window. Evaluation of the hila is somewhat limited without contrast. There is vascular calcification including coronary involvement. Adrenal glands appear mildly thickened without definite mass.

IMPRESSION:

1. There is a noncalcified mass density of concern for a neoplasm in the left lower lobe posteriorly.
2. There are bilateral apical opacities right greater than left which may be due to scarring. In light of asymmetry a superimposed mass cannot be excluded. PET scan may be helpful to evaluate the various abnormalities. The lungs appear hyperexpanded and there are regions of peribronchial thickening and interstitial density which are consistent
-
-

[page 9 of 10]
AMERICAN MEDICAL ASSOCIATION 535 N. Dearborn Chicago, Ill. 60610-5406

Source: NCI Genomic Data Commons file 5dee7d42-d502-4b8a-b2f5-716386cb9f07 (TCGA-67-3773.E5B82F07-698E-4DFF-9D33-748790E40811.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).